Somatic mutation profile of tumor specimen TCGA-BR-8589-01A (aliquot TCGA-BR-8589-01A-11D-2394-08) from TCGA case TCGA-BR-8589, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.7 years (20,727 days).
Specimen TCGA-BR-8589-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08ccda77-4045-4568-b11a-98551cfdf0fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8589-10A (Blood Derived Normal), aliquot TCGA-BR-8589-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b525d78b-8dec-401f-b84b-2af398aa0fca

The open-access MAF lists 1,187 somatic variants for this specimen: 939 protein-altering or splice-affecting, 224 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 889, Silent 224, Nonsense Mutation 15, Splice Region 12, Splice Site 11, RNA 10, Intron 8, Frame Shift Del 6, Frame Shift Ins 3, 3'UTR 3, Nonstop Mutation 2, 3'Flank 2.

Variants (750 of 1,187; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 16/83 reads (19%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- AAAS | c.1184T>C p.L395P | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs766356863, COSV52934561; called by muse, mutect2, varscan2
- AARS2 | c.2589A>C p.Q863H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55117864; called by muse, mutect2
- ABCA13 | c.7277T>G p.L2426R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV71295496; called by muse, mutect2, varscan2
- ABCA13 | c.8416A>C p.N2806H | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV71295502; called by muse, mutect2
- ABCB4 | c.1306A>G p.S436G | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55942558; called by muse, mutect2, varscan2
- ABI3BP | c.730A>C p.T244P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52553000; called by muse, mutect2, varscan2
- ABL2 | c.996A>C p.E332D (on ENST00000502732 / NM_007314.4; = p.E317D on NM_005158.5) | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61021213; called by muse, mutect2, varscan2
- ABL2 | c.551A>G p.E184G (on ENST00000502732 / NM_007314.4; = p.E169G on NM_005158.5) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61021230; called by muse, mutect2
- AC090517.4 | c.565T>G p.S189A | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV51001519; called by muse, mutect2, varscan2
- ACACB | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV58148136; called by muse, mutect2, varscan2
- ACACB | c.3022A>T p.S1008C | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV58148149; called by muse, mutect2, varscan2
- ACE | c.3149A>C p.N1050T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52013836; called by muse, mutect2, varscan2
- ACSBG1 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs749048599, COSV51911438; called by muse, mutect2, varscan2
- ACSS1 | c.1838A>T p.K613M | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as COSV60225424; called by muse, mutect2, varscan2
- ACTN2 | c.1145A>G p.E382G | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766953315, COSV63978614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN2 | c.1786A>T p.S596C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV100856528, COSV63978620; called by muse, mutect2, varscan2
- ACYP2 | c.217A>G p.S73G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as COSV57820950; called by muse, mutect2, varscan2
- ADAMTS12 | c.692A>C p.N231T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs200137220, COSV61282005; called by muse, mutect2, varscan2
- ADAMTS16 | c.3637A>G p.K1213E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV57008755; called by muse, mutect2
- ADAR | c.2858A>G p.K953R | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.423); catalogued as COSV52721959; called by muse, mutect2, varscan2
- ADCY8 | c.3245T>C p.F1082S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.157); catalogued as COSV53930526; called by muse, varscan2
- ADCY8 | c.3203T>G p.L1068R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53930537; called by muse, varscan2
- ADGRE2 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs374432034; called by muse, mutect2, varscan2
- ADGRG4 | c.8899T>G p.F2967V | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV54968578; called by muse, mutect2, varscan2
- ADGRL2 | c.3037T>G p.L1013V (on ENST00000370717 / NM_001366005.1; = p.L1000V on NM_012302.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.305); catalogued as COSV54691862; called by muse, mutect2, varscan2
- ADH1B | c.1019A>C p.K340T | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV59299067; called by muse, mutect2
- ADH1B | c.343A>C p.N115H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs952025294, COSV59299077; called by muse, mutect2, varscan2
- ADIPOR2 | c.880T>G p.L294V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.034); catalogued as COSV63947841; called by muse, mutect2, varscan2
- ADRA2A | c.1100A>G p.E367G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV54530303; called by muse, varscan2
- ADSS2 | c.506T>G p.V169G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV63696422; called by muse, mutect2, varscan2
- AFAP1L2 | c.2438A>T p.E813V (on ENST00000304129 / NM_001351075.1; = p.E809V on NM_032550.3 and 11 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV58419052; called by muse, mutect2, varscan2
- AFF3 | c.1357T>G p.F453V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as COSV57876076; called by muse, mutect2, varscan2
- AFTPH | c.110T>G p.V37G | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV53222496; called by muse, mutect2, varscan2
- AGBL2 | c.2302A>C p.N768H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV54095925; called by muse, mutect2, varscan2
- AHNAK | c.15428T>G p.V5143G | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV57233339; called by muse, mutect2, varscan2
- AHNAK2 | c.6590A>T p.K2197M | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60918105, COSV60932599; called by muse, mutect2, varscan2
- AKR1B15 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV71152881; called by muse, mutect2, varscan2
- ALDH1L1 | c.1406A>C p.K469T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV56419934; called by muse, mutect2, varscan2
- ALDH8A1 | c.1020T>G p.S340R | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV55644584; called by muse, mutect2, varscan2
- ALMS1 | c.761T>A p.L254Q | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52514125, COSV52523404; called by muse, mutect2, varscan2
- ALPK3 | c.587T>G p.I196S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV51940894, COSV99360705; called by muse, mutect2, varscan2
- ALPK3 | c.4942A>G p.K1648E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1273857977, COSV51940912; called by muse, mutect2, varscan2
- ANGPTL1 | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52365929, COSV52368387; called by muse, mutect2, varscan2
- ANK2 | c.8265A>C p.E2755D | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV52191951; called by muse, mutect2, varscan2
- ANKAR | c.640A>C p.I214L | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV55618714; called by muse, mutect2, varscan2
- ANKAR | c.975T>G p.F325L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1413006423, COSV55618728; called by muse, mutect2, varscan2
- ANKAR | c.2618T>G p.F873C | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs750042792, COSV55618751; called by muse, mutect2, varscan2
- ANTXR2 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56320347; called by muse, mutect2, varscan2
- AP3M1 | c.1075A>C p.N359H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53015221; called by muse, mutect2, varscan2
- AP3M2 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as rs200841873, COSV51530909; called by muse, mutect2, varscan2
- APAF1 | c.304T>G p.S102A | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV54491324; called by muse, mutect2, varscan2
- APLP1 | c.669T>G p.V223= | Splice Region (SNP) | VAF 7/50 reads (14%) | catalogued as COSV55707352; called by muse, mutect2, varscan2
- APOA1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483165479, COSV52636942; called by muse, mutect2, varscan2
- APOB | c.11288T>G p.L3763R | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV51955274; called by muse, mutect2, varscan2
- APOB | c.4411T>G p.L1471V | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV51955292; called by muse, mutect2, varscan2
- APOBEC2 | c.246A>T p.Q82H | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV55143728; called by muse, mutect2, varscan2
- AQP3 | c.179A>C p.N60T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV53049170, COSV99955443; called by muse, mutect2, varscan2
- ARFGEF1 | c.3709T>A p.L1237I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51618010; called by muse, mutect2
- ARHGAP32 | c.3428A>G p.H1143R (on ENST00000310343 / NM_001378025.1; = p.H794R on NM_014715.4) | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV59843681; called by muse, mutect2
- ARHGAP33 | c.1559A>G p.D520G | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.703); catalogued as COSV50177332; called by muse, mutect2, varscan2
- ARHGAP5 | c.1046T>C p.L349P | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61539599; called by muse, mutect2, varscan2
- ARHGAP9 | c.25A>G p.S9G | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100712542; called by muse, mutect2, varscan2
- ARHGEF18 | c.743G>A p.R248H (on ENST00000359920 / NM_001130955.2; = p.R144H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs960519789, COSV60469637; called by muse, mutect2, varscan2
- ARID1A | c.5221C>T p.Q1741* | Nonsense Mutation (SNP) | VAF 25/163 reads (15%) | catalogued as COSV61372948; called by muse, mutect2, varscan2
- ARL1 | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55371152; called by muse, varscan2
- ARNTL | c.670A>T p.T224S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV62989127; called by muse, mutect2
- ART3 | c.430A>T p.R144* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as COSV61916423; called by muse, mutect2, varscan2
- ASAP2 | c.1363A>T p.T455S | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55639693; called by muse, mutect2
- ASB9 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV66852419; called by muse, mutect2, varscan2
- ASH1L | c.4165T>G p.S1389A | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.136); catalogued as COSV64214498; called by muse, mutect2, varscan2
- ASH1L | c.2173A>G p.R725G | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as rs765574300, COSV64214503; called by muse, mutect2, varscan2
- ASPH | c.857A>G p.N286S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.185); catalogued as COSV62861715; called by muse, mutect2, varscan2
- ATAD2B | c.241A>C p.S81R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53206407; called by muse, mutect2, varscan2
- ATAD5 | c.2839T>A p.L947M | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58979836; called by muse, mutect2, varscan2
- ATG12 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57243817; called by muse, mutect2, varscan2
- ATG2B | c.3161T>G p.V1054G | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV63426076; called by muse, mutect2, varscan2
- ATP11A | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329268153, COSV52125986; called by muse, mutect2, varscan2
- ATP1A3 | c.2270A>C p.N757T (on ENST00000545399 / NM_001256214.2; = p.N744T on NM_152296.5) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57491650; called by muse, mutect2, varscan2
- ATP1B4 | c.564T>G p.G188= (on ENST00000218008 / NM_001142447.3; = p.G184= on NM_012069.5) | Splice Region (SNP) | VAF 28/69 reads (41%) | catalogued as COSV54315360; called by muse, mutect2, varscan2
- ATP6V1C1 | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.766); catalogued as COSV67778997; called by muse, mutect2, varscan2
- ATR | c.4838A>C p.K1613T | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV63393373; called by muse, mutect2
- ATXN1 | c.1085T>A p.V362E | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55232815; called by muse, mutect2, varscan2
- B3GALT1 | c.362A>C p.N121T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as COSV59910044; called by muse, mutect2, varscan2
- B4GALT4 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63296518; called by muse, mutect2, varscan2
- B4GAT1 | c.1142A>C p.K381T | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV60820839; called by muse, mutect2, varscan2
- BAIAP2 | c.599A>G p.K200R | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.056); catalogued as COSV58341208; called by muse, mutect2, varscan2
- BAP1 | c.1622T>G p.V541G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV56241386; called by muse, mutect2, varscan2
- BARX2 | c.800A>C p.E267A | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); catalogued as COSV55652630; called by muse, mutect2, varscan2
- BCR | c.2105A>C p.K702T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as COSV59936290; called by muse, mutect2, varscan2
- BDNF | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59238972; called by muse, mutect2, varscan2
- BDP1 | c.5274A>C p.K1758N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV62435339; called by muse, mutect2, varscan2
- BECN1 | c.1091A>G p.K364R | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59312915; called by muse, mutect2, varscan2
- BHMT | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.225); catalogued as rs746344824, COSV57155951; called by muse, mutect2, varscan2
- BIRC6 | c.14059A>C p.S4687R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70206910; called by muse, mutect2, varscan2
- BMP7 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs771679633, COSV67780443; called by muse, mutect2, varscan2
- BNC2 | c.1219A>G p.N407D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV66158496; called by muse, mutect2, varscan2
- BNC2 | c.110T>G p.V37G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV66142178, COSV66158505; called by mutect2, varscan2
- BNIP3 | c.385T>G p.C129G | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64044413; called by muse, mutect2, varscan2
- BOLL | c.264A>C p.K88N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV56577823; called by muse, mutect2, varscan2
- BPI | c.205T>A p.S69T (on ENST00000262865; = p.S65T on NM_001725.3) | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.204); catalogued as COSV53408790; called by muse, mutect2, varscan2
- BPIFA1 | c.652T>G p.L218V | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV62825324; called by muse, mutect2, varscan2
- BPIFB4 | c.655A>C p.S219R | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV64952558; called by muse, mutect2
- BPIFB6 | c.986A>G p.K329R | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV62756857; called by muse, mutect2, varscan2
- BRCA1 | c.3773A>G p.E1258G | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV58801247; called by muse, mutect2
- BRD3 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV57707027; called by muse, mutect2, varscan2
- BRSK1 | c.379A>T p.R127* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV58670569; called by muse, mutect2, varscan2
- BTAF1 | c.1932A>T p.Q644H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.935); catalogued as COSV56440114; called by muse, mutect2, varscan2
- BTN3A1 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50025457; called by muse, mutect2, varscan2
- BUB1B | c.1923A>C p.E641D | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.612); catalogued as COSV55017283; called by muse, mutect2, varscan2
- C10orf90 | c.68A>C p.K23T | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV52965180; called by muse, mutect2, varscan2
- C16orf71 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.154); catalogued as COSV54795194; called by muse, mutect2, varscan2
- C16orf82 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs1219609011; called by muse, mutect2
- C20orf194 | c.1920T>G p.F640L | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52703904; called by muse, mutect2, varscan2
- C2orf16 | c.4789A>C p.N1597H | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as COSV62678694; called by muse, mutect2, varscan2
- CADM2 | c.944-2A>G p.X315_splice (on ENST00000407528 / NM_001167674.2; = p.X317_splice on NM_153184.4) | Splice Site (SNP) | VAF 59/239 reads (25%) | catalogued as COSV67408003; called by muse, mutect2, varscan2
- CAMSAP2 | c.3720A>C p.K1240N (on ENST00000236925 / NM_001297707.2; = p.K1229N on NM_203459.3) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV52678528; called by muse, mutect2, varscan2
- CAPN6 | c.1871A>G p.K624R | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV60697509; called by muse, mutect2, varscan2
- CARD17 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 31/314 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs200199103, COSV65215381, COSV65215772; called by muse, mutect2
- CASQ1 | c.898T>G p.L300V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63624617; called by muse, mutect2, varscan2
- CATSPER1 | c.1108A>G p.I370V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs778848109, COSV56413859; called by muse, mutect2, varscan2
- CATSPERE | c.1502T>G p.F501C | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100835196, COSV63682607; called by muse, mutect2, varscan2
- CCDC136 | c.2843T>C p.V948A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52805922; called by muse, mutect2, varscan2
- CCDC144A | c.771T>G p.D257E | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV60702362; called by muse, mutect2, varscan2
- CCDC54 | c.972A>C p.E324D | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.851); catalogued as COSV53760043; called by muse, mutect2, varscan2
- CCDC58 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52248283; called by muse, mutect2
- CCDC81 | c.826T>A p.L276M (on ENST00000445632 / NM_001156474.2; = p.L186M on NM_021827.4) | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53582068; called by muse, mutect2
- CCL1 | c.56A>C p.E19A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV56775782; called by muse, mutect2, varscan2
- CCNB3 | c.820A>T p.T274S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV52070382, COSV52080518; called by muse, mutect2, varscan2
- CD163L1 | c.2164A>C p.N722H | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV58023579, COSV58025733; called by muse, mutect2, varscan2
- CD300E | c.314A>C p.K105T | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as COSV60791905; called by muse, mutect2, varscan2
- CD33 | c.925-2A>G p.X309_splice | Splice Site (SNP) | VAF 22/70 reads (31%) | catalogued as COSV51801109, COSV51805320; called by muse, mutect2, varscan2
- CD38 | c.401A>G p.Q134R | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV56889794; called by muse, mutect2, varscan2
- CDC37L1 | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as COSV67866451; called by muse, mutect2, varscan2
- CDH23 | c.5842T>G p.F1948V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV56493235; called by muse, mutect2, varscan2
- CDH9 | c.1401A>C p.K467N | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV50503202; called by muse, mutect2, varscan2
- CDHR2 | c.2117A>G p.E706G | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56146125; called by muse, mutect2
- CDK19 | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60454050; called by muse, mutect2
- CDKL2 | c.542A>G p.K181R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV56735690; called by muse, mutect2, varscan2
- CEACAM8 | c.71T>G p.L24R | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54991214, COSV54992025; called by muse, mutect2, varscan2
- CECR2 | c.3970G>A p.A1324T (on ENST00000342247 / NM_001290047.2; = p.A1140T on NM_001290046.1) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs897079322, COSV52849253; called by muse, mutect2, varscan2
- CELSR1 | c.3758T>G p.V1253G | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV53101119; called by muse, mutect2, varscan2
- CELSR3 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV51165578; called by muse, mutect2, varscan2
- CEP112 | c.1742A>T p.K581I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV67145138; called by muse, mutect2, varscan2
- CEP41 | c.922A>C p.K308Q | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56221655; called by muse, mutect2, varscan2
- CFAP161 | c.113T>G p.L38R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99715641; called by muse, mutect2, varscan2
- CFAP91 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as COSV56341432, COSV56345257; called by muse, mutect2
- CFTR | c.2578A>C p.I860L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV50113761; called by muse, mutect2, varscan2
- CHAF1A | c.934T>G p.F312V | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV56676849; called by muse, mutect2, varscan2
- CHRM3 | c.415T>A p.L139M | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV55106834; called by muse, mutect2, varscan2
- CIT | c.1781T>G p.L594R | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.034); catalogued as COSV55885012; called by muse, mutect2
- CLASP2 | c.1607A>G p.K536R | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.047); catalogued as COSV56295324; called by muse, mutect2, varscan2
- CLEC16A | c.2351A>C p.K784T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as COSV55491805; called by muse, mutect2, varscan2
- CLEC4C | c.151A>C p.T51P | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.206); catalogued as COSV63583351; called by muse, mutect2, varscan2
- CLNS1A | c.291A>C p.E97D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54441036; called by muse, mutect2
- CMYA5 | c.495A>C p.K165N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs373060111; called by muse, mutect2, varscan2
- CNGB3 | c.1001T>G p.F334C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60699400; called by muse, mutect2, varscan2
- CNNM4 | c.2092T>G p.F698V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1169299457, COSV65662236; called by muse, mutect2, varscan2
- CNTN1 | c.860A>C p.E287A | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV61646347; called by muse, mutect2
- CNTN4 | c.188A>C p.K63T | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as COSV68580113; called by muse, mutect2, varscan2
- COG5 | c.188A>C p.K63T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV51765885; called by muse, mutect2, varscan2
- COL6A6 | c.1894A>C p.S632R | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62027645; called by muse, mutect2, varscan2
- CPAMD8 | c.1831G>A p.V611I (on ENST00000651564; = p.V564I on NM_015692.5) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs374200163; called by muse, mutect2, varscan2
- CR1 | c.4472T>G p.I1491S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65464337; called by muse, mutect2, varscan2
- CREBRF | c.524A>C p.K175T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as COSV51636849; called by muse, mutect2, varscan2
- CRLF2 | c.519A>C p.E173D | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV101053864; called by muse, varscan2
- CRNKL1 | c.1052A>C p.N351T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.108); catalogued as COSV55649340; called by muse, mutect2, varscan2
- CROT | c.1615T>G p.F539V | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58977155; called by muse, mutect2, varscan2
- CRYBG3 | c.6340A>T p.R2114* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as COSV51716666; called by muse, mutect2, varscan2
- CSF2RA | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as rs1414815824, COSV62627038; called by muse, mutect2, varscan2
- CSNK2A2 | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52644304; called by muse, mutect2, varscan2
- CTSF | c.901A>T p.T301S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV59750798; called by muse, mutect2, varscan2
- CTTN | c.1493T>C p.V498A | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV57236674; called by muse, mutect2, varscan2
- CUBN | c.2459A>C p.E820A | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.253); catalogued as rs1160105562, COSV64728573; called by muse, mutect2, varscan2
- CXCR1 | c.155T>G p.L52R | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55283197; called by muse, mutect2, varscan2
- CYLD | c.2705A>T p.N902I | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61094788; called by muse, mutect2, varscan2
- CYP17A1 | c.86A>T p.K29M | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV64005170; called by muse, mutect2, varscan2
- CYP19A1 | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53062817; called by muse, mutect2, varscan2
- CYP2J2 | c.269T>G p.L90R | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV64607304; called by muse, mutect2, varscan2
- CYP39A1 | c.71A>G p.K24R | Missense Mutation (SNP) | VAF 39/374 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV51499699; called by muse, mutect2, varscan2
- CYP4Z1 | c.299A>C p.K100T | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV61966943; called by muse, mutect2, varscan2
- CYTH1 | c.191A>C p.K64T | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV63123896; called by muse, mutect2, varscan2
- DCAF4L1 | c.662T>G p.F221C | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV60787471, COSV60788788; called by muse, mutect2, varscan2
- DDX10 | c.874T>G p.Y292D | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59440790; called by muse, mutect2
- DENND5A | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60238313; called by mutect2, varscan2
- DHX30 | c.2911A>T p.S971C (on ENST00000445061 / NM_138615.3; = p.S932C on NM_014966.3) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV53143435; called by muse, mutect2, varscan2
- DHX9 | c.1175A>C p.K392T | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.132); catalogued as COSV62362591; called by muse, mutect2, varscan2
- DIAPH3 | c.1948A>C p.N650H (on ENST00000400324 / NM_001042517.2; = p.N387H on NM_030932.3) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57382236; called by muse, mutect2
- DIRAS3 | c.690A>G p.*230Wext*15 | Nonstop Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV63971287; called by muse, mutect2, varscan2
- DMAC2L | c.338A>C p.K113T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.219); catalogued as COSV55414532; called by muse, mutect2, varscan2
- DMP1 | c.1240T>G p.F414V | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV56822356; called by muse, mutect2, varscan2
- DMP1 | c.1392A>C p.E464D | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV56822366; called by muse, mutect2, varscan2
- DMXL2 | c.6311A>G p.K2104R | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV51857539; called by muse, mutect2, varscan2
- DMXL2 | c.4823A>C p.E1608A | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV51857545; called by muse, mutect2
- DNAH10 | c.7928A>G p.D2643G (on ENST00000409039; = p.D2582G on NM_207437.3) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69003508; called by muse, mutect2, varscan2
- DNAH5 | c.2365T>G p.L789V | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV54255801; called by muse, mutect2, varscan2
- DNAH8 | c.5127A>C p.E1709D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV59484217; called by muse, mutect2
- DNAH9 | c.3117A>C p.E1039D | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.163); catalogued as rs149721373, COSV52379456; called by muse, mutect2, varscan2
- DNAI1 | c.661T>G p.F221V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV54279485, COSV54279893; called by muse, mutect2, varscan2
- DNMBP | c.1558A>G p.R520G | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1351250528, COSV60634073; called by muse, mutect2, varscan2
- DOCK9 | c.5795A>C p.K1932T (on ENST00000376460 / NM_001366676.2; = p.K1933T on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV59645533; called by muse, mutect2, varscan2
- DPYSL3 | c.149T>G p.I50S | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV58331609; called by muse, mutect2, varscan2
- DPYSL5 | c.1379A>C p.K460T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs1409009410, COSV56516814; called by muse, mutect2, varscan2
- DRC1 | c.409A>T p.I137F | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56536367; called by muse, mutect2, varscan2
- DRC7 | c.1937A>C p.K646T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as COSV61058069; called by muse, mutect2, varscan2
- DSCAML1 | c.1286A>T p.E429V (on ENST00000321322; = p.E369V on NM_020693.4) | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV58404028; called by muse, mutect2, varscan2
- DST | c.6149T>G p.L2050R | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV99760611; called by muse, mutect2, varscan2
- DST | c.4791T>G p.I1597M | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99760613; called by muse, mutect2, varscan2
- DUOX1 | c.3623T>G p.F1208C | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58486933; called by muse, mutect2, varscan2
- DUSP16 | c.599T>G p.F200C | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53810106; called by muse, mutect2
- DYNC2H1 | c.7077A>C p.K2359N | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62108308; called by muse, mutect2, varscan2
- ECT2 | c.2493A>C p.K831N (on ENST00000392692 / NM_001349098.2; = p.K800N on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV51695021; called by muse, mutect2, varscan2
- EDAR | c.113A>C p.N38T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV51508275; called by muse, mutect2, varscan2
- EDEM1 | c.1177A>C p.N393H | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV56584467; called by muse, mutect2, varscan2
- EDNRB | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV57521250; called by muse, mutect2, varscan2
- EDRF1 | c.393A>C p.K131N | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV61766531; called by muse, mutect2, varscan2
- EEA1 | c.1233A>C p.Q411H | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59290422; called by muse, mutect2, varscan2
- EFHC2 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69555728; called by muse, mutect2, varscan2
- EFR3A | c.1379T>C p.F460S | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV54463016; called by muse, mutect2, varscan2
- EHD3 | c.688A>C p.M230L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV59033237; called by muse, mutect2, varscan2
- EIF3K | c.479A>G p.E160G | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs1423664110, COSV50264708; called by muse, mutect2, varscan2
- EIF5B | c.3468A>C p.E1156D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV51491065; called by muse, mutect2
- ENPEP | c.2861T>G p.L954R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99488226; called by muse, mutect2, varscan2
- ENPP6 | c.1304T>A p.L435H | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV57073057; called by muse, mutect2
- ENTPD4 | c.846A>C p.E282D | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1232968466, COSV100652821; called by muse, mutect2, varscan2
- EPHA3 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60729945; called by muse, mutect2, varscan2
- EPHA4 | c.316A>T p.R106W | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56045347; called by muse, mutect2
- EPHB3 | c.1073A>C p.E358A | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57809608; called by muse, mutect2
- EPHB3 | c.2125A>C p.I709L | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57809613; called by muse, mutect2, varscan2
- EPX | c.1895T>G p.L632R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56599660; called by muse, mutect2, varscan2
- ETV5 | c.1337A>C p.K446T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60507150; called by muse, mutect2, varscan2
- EXPH5 | c.5809A>G p.S1937G | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV56198898; called by muse, mutect2, varscan2
- EYA1 | c.17T>C p.L6P | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58175113; called by muse, mutect2
- F2R | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV59930336; called by muse, mutect2
- F5 | c.2591A>C p.K864T | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV63129014; called by muse, mutect2, varscan2
- FAM13B | c.2693A>C p.K898T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50376108; called by muse, mutect2, varscan2
- FAM189A2 | c.262T>A p.F88I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV57386421; called by muse, mutect2, varscan2
- FASTKD1 | c.2344T>G p.L782V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52931826; called by muse, mutect2
- FBH1 | c.1435A>C p.K479Q (on ENST00000362091 / NM_178150.3; = p.K530Q on NM_032807.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.147); catalogued as COSV62984717; called by muse, mutect2, varscan2
- FBXL13 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV57545280; called by muse, mutect2
- FBXO10 | c.2514A>G p.K838= | Splice Region (SNP) | VAF 11/58 reads (19%) | catalogued as COSV52836047; called by muse, mutect2, varscan2
- FBXO24 | c.633A>C p.E211D (on ENST00000241071 / NM_033506.3; = p.E249D on NM_012172.5) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV53830409; called by muse, mutect2, varscan2
- FBXO40 | c.659A>C p.N220T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.053); catalogued as COSV57528261; called by muse, mutect2, varscan2
- FBXO8 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV67032392; called by muse, mutect2, varscan2
- FFAR4 | c.57A>C p.Q19H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.078); catalogued as COSV65179942; called by muse, mutect2, varscan2
- FGR | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64969863; called by muse, mutect2, varscan2
- FMNL3 | c.790A>C p.R264= | Splice Region (SNP) | VAF 8/102 reads (8%) | catalogued as COSV53308449; called by muse, mutect2
- FMO3 | c.1484A>C p.K495T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV63008749; called by muse, mutect2, varscan2
- FNDC1 | c.1950T>G p.D650E | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs764507497, COSV51948784; called by muse, mutect2, varscan2
- FNDC3A | c.1322T>G p.F441C (on ENST00000492622 / NM_001079673.2; = p.F385C on NM_014923.5) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68135360; called by muse, mutect2, varscan2
- FOLR3 | c.682T>G p.F228V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV61531071; called by muse, mutect2, varscan2
- FOXK1 | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV61065615; called by muse, mutect2, varscan2
- FRAS1 | c.3957A>C p.Q1319H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53653040; called by mutect2, varscan2
- FREM2 | c.4276A>C p.S1426R | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV54854484; called by muse, mutect2, varscan2
- FSD2 | c.1043A>C p.E348A | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58013453; called by muse, mutect2, varscan2
- FZD2 | c.1427T>A p.V476D | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100190459, COSV59530450; called by muse, mutect2, varscan2
- FZD8 | c.157A>G p.M53V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65967832; called by muse, mutect2, varscan2
- GABRB1 | c.543T>A p.S181R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55001581; called by muse, mutect2, varscan2
- GAD2 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52152365, COSV52169752; called by muse, mutect2, varscan2
- GCC2 | c.3877A>C p.S1293R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV59180447; called by muse, mutect2, varscan2
- GCN1 | c.1784T>G p.L595R | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.055); catalogued as COSV56115570; called by muse, mutect2, varscan2
- GDF6 | c.140A>C p.K47T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV54628214; called by muse, mutect2, varscan2
- GFI1B | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59747443; called by muse, mutect2
- GIMAP6 | c.102A>C p.E34D | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.286); catalogued as COSV61035025; called by muse, mutect2, varscan2
- GK | c.1111T>G p.S371A (on ENST00000427190 / NM_001205019.2; = p.S365A on NM_000167.6) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66732604; called by muse, mutect2, varscan2
- GLB1L | c.1772T>C p.F591S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV55479334; called by muse, mutect2, varscan2
- GLRA4 | c.386A>C p.K129T | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV65457092; called by muse, mutect2, varscan2
- GLUD2 | c.774A>T p.K258N | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60152941, COSV60153378; called by muse, mutect2, varscan2
- GLUL | c.445T>C p.W149R | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59383561; called by muse, mutect2, varscan2
- GNPTAB | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1377707026, COSV63261225; called by muse, mutect2
- GOLGA4 | c.5087A>C p.K1696T | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV62714229; called by muse, mutect2, varscan2
- GOLGB1 | c.4578A>C p.Q1526H | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV61463442; called by muse, mutect2, varscan2
- GPR139 | c.847T>G p.F283V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV58505354; called by muse, mutect2
- GPR158 | c.3143C>A p.S1048Y | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs149957388; called by muse, mutect2, varscan2
- GPRC6A | c.812T>G p.V271G | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59956318; called by muse, mutect2, varscan2
- GPSM2 | c.843A>C p.E281D | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51444864; called by muse, mutect2, varscan2
- GRAMD2B | c.758A>T p.D253V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53510454; called by muse, mutect2, varscan2
- GRIA3 | c.2492T>C p.L831P | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52082260; called by muse, mutect2, varscan2
- GRIK1 | c.811A>G p.R271G | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV58733996; called by muse, mutect2, varscan2
- GRIK3 | c.572T>C p.L191P | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66147785; called by muse, mutect2, varscan2
- GRIN2A | c.202A>C p.N68H | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV58058446; called by muse, mutect2
- GRM1 | c.3503A>C p.E1168A | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV51368270; called by muse, mutect2, varscan2
- GSN | c.910T>C p.S304P | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58001943; called by muse, mutect2, varscan2
- GSTO2 | c.619A>T p.M207L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58539894; called by muse, mutect2, varscan2
- GTF2H4 | c.800A>C p.E267A | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52561450; called by muse, mutect2, varscan2
- GYPB | c.221T>A p.I74N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1043433456, COSV51638699; called by muse, mutect2, varscan2
- HDAC7 | c.2092G>A p.A698T (on ENST00000427332; = p.A737T on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs766456680, COSV50410489; called by muse, mutect2
- HDC | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs1334335115, COSV51083788; called by muse, mutect2, varscan2
- HECTD3 | c.1988A>T p.K663M | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV64670982; called by muse, mutect2, varscan2
- HERC2 | c.4670A>G p.K1557R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as COSV55352738; called by muse, mutect2, varscan2
- HERC4 | c.1765T>G p.F589V | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV53275882; called by muse, mutect2
- HIVEP3 | c.1958A>C p.K653T | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56024853; called by muse, mutect2, varscan2
- HLA-B | c.710T>G p.I237S | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV69523218; called by muse, mutect2
- HMGB2 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV56634237; called by muse, mutect2, varscan2
- HOATZ | c.432A>C p.K144N (on ENST00000375618 / NM_001100388.1; = p.K171N on NM_207430.2) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771057725, COSV100239656; called by muse, mutect2, varscan2
- HOXA9 | c.399A>C p.K133N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58656808; called by muse, mutect2, varscan2
- HOXC11 | c.752T>C p.F251S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54534198; called by muse, mutect2, varscan2
- HP | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as rs1384740820, COSV100577661; called by muse, mutect2, varscan2
- HPSE | c.1385A>G p.K462R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV60988955; called by muse, mutect2, varscan2
- HS3ST5 | c.389A>C p.E130A | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV57153159; called by muse, mutect2, varscan2
- HSD17B13 | c.694A>C p.R232= | Splice Region (SNP) | VAF 10/83 reads (12%) | catalogued as COSV56347462; called by muse, mutect2, varscan2
- HSD17B4 | c.941A>T p.Q314L (on ENST00000414835 / NM_001199291.3; = p.Q289L on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV99820236; called by muse, mutect2
- HSPA4 | c.1756T>G p.L586V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV59183723; called by muse, mutect2, varscan2
- HTR7 | c.998T>C p.V333A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53293554; called by muse, mutect2, varscan2
- HTRA2 | c.538T>C p.S180P | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51215717; called by muse, mutect2
- HUS1 | c.687A>C p.E229D | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs200031230, COSV51840657; called by muse, mutect2, varscan2
- HUS1B | c.614A>C p.K205T | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV57872422; called by muse, mutect2, varscan2
- HYDIN | c.4937A>C p.K1646T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV59272599; called by muse, mutect2, varscan2
- HYLS1 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV54993025; called by muse, mutect2, varscan2
- IFNW1 | c.502A>G p.R168G | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66522522; called by muse, mutect2
- IFT122 | c.1060A>G p.T354A (on ENST00000348417 / NM_052989.3; = p.T295A on NM_018262.4) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV56209013; called by muse, mutect2, varscan2
- IFT122 | c.2996T>A p.L999H (on ENST00000348417 / NM_052989.3; = p.L940H on NM_018262.4) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56209025; called by muse, mutect2, varscan2
- IGF1R | c.52T>A p.F18I | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51400889, COSV51408758; called by muse, mutect2, varscan2
- IGHD | c.571T>G p.F191V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV101163047; called by muse, mutect2
- IGKV3-11 | c.169C>G p.Q57E | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs374140505; called by muse, mutect2
- IL12A | c.698T>G p.L233R | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59760273; called by muse, mutect2, varscan2
- IL17RC | c.2290G>A p.D764N (on ENST00000295981 / NM_153461.4; = p.D678N on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV55975289; called by muse, mutect2, varscan2
- IL21 | c.153T>G p.N51K | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV52647468; called by muse, mutect2, varscan2
- IMP4 | c.590A>T p.K197M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as rs751505217, COSV52092945; called by muse, mutect2, varscan2
- IMPG2 | c.1600A>T p.S534C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV51986244, COSV99514564; called by muse, mutect2, varscan2
- INPP5B | c.2936A>C p.K979T (on ENST00000373023; = p.K899T on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV65963274; called by muse, mutect2, varscan2
- IPO11 | c.539T>G p.F180C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV57583559; called by muse, mutect2
- IPO7 | c.395A>T p.K132I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101121855; called by muse, mutect2, varscan2
- IPO7 | c.1215A>T p.K405N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63352932; called by muse, mutect2, varscan2
- IQGAP1 | c.2022A>C p.K674N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51592009; called by muse, mutect2, varscan2
- IRAG1 | c.2016T>A p.S672= | Splice Region (SNP) | VAF 8/61 reads (13%) | catalogued as COSV70213178; called by muse, mutect2
- IRAK2 | c.710A>C p.K237T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56536166; called by muse, mutect2, varscan2
- ITGAD | c.32-2A>G p.X11_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as COSV66760522; called by muse, mutect2
- ITGAL | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV63324694; called by muse, mutect2, varscan2
- ITPR2 | c.5528T>C p.L1843S | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV67277005; called by muse, mutect2, varscan2
- JADE1 | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56909736; called by muse, mutect2, varscan2
- JKAMP | c.572A>C p.K191T (on ENST00000554271 / NM_001284201.1; = p.K177T on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.042); catalogued as COSV54201738; called by muse, mutect2, varscan2
- KCNG1 | c.845A>G p.E282G | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65370600; called by muse, mutect2
- KCNH6 | c.675G>A p.Q225= | Splice Region (SNP) | VAF 18/57 reads (32%) | catalogued as COSV59008188; called by muse, mutect2, varscan2
- KCNH6 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779809321, COSV59001597; called by muse, mutect2, varscan2
- KCNIP2 | c.380A>C p.N127T (on ENST00000356640 / NM_173191.3; = p.N142T on NM_014591.5) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53308753; called by muse, mutect2, varscan2
- KCNK9 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as rs1237927464, COSV57278660; called by muse, mutect2, varscan2
- KCNMA1 | c.790T>G p.L264V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54292566; called by muse, mutect2, varscan2
- KCNQ5 | c.1995T>G p.D665E | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV59684983; called by muse, mutect2, varscan2
- KCNQ5 | c.2657T>C p.F886S | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV59684993; called by muse, mutect2
- KCNS1 | c.929T>G p.I310S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV60261245; called by muse, mutect2, varscan2
- KCNV1 | c.1306T>G p.F436V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV52089428; called by muse, mutect2, varscan2
- KDM1B | c.2045T>C p.F682S (on ENST00000449850; = p.F449S on NM_153042.4) | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52814889; called by muse, mutect2, varscan2
- KDM5A | c.1121A>G p.K374R | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV66996713; called by muse, mutect2, varscan2
- KIAA0319 | c.1642T>G p.L548V | Missense Mutation (SNP) | VAF 55/455 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1330952859, COSV65502241; called by muse, mutect2, varscan2
- KIAA0319 | c.1238A>C p.N413T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV65502248; called by muse, mutect2, varscan2
- KIAA0408 | c.1418A>G p.K473R | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.294); catalogued as COSV100847094; called by muse, mutect2, varscan2
- KIAA0753 | c.456A>C p.Q152H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.568); catalogued as COSV63819087; called by muse, mutect2
- KIAA1109 | c.59T>G p.L20R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52695520; called by muse, mutect2, varscan2
- KIAA1328 | c.1291C>T p.H431Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54467307; called by muse, mutect2, varscan2
- KIF13A | c.5006T>C p.L1669P | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1384933070, COSV52467313; called by muse, mutect2, varscan2
- KIF2B | c.1462A>C p.N488H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV52136065; called by muse, varscan2
- KMT2D | c.3179A>C p.K1060T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV56491979; called by muse, mutect2, varscan2
- KRT6A | c.893T>C p.L298P | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV58108135; called by muse, mutect2
- KRTAP19-8 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV66998547; called by muse, mutect2, varscan2
- KRTAP5-9 | c.388T>G p.C130G | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV73200288; called by muse, mutect2, varscan2
- L3MBTL1 | c.1405T>G p.F469V (on ENST00000418998 / NM_001377303.1; = p.F379V on NM_015478.7) | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64229792; called by muse, mutect2, varscan2
- LAMA1 | c.6017A>G p.D2006G | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs772153716, COSV67545102; called by muse, mutect2, varscan2
- LAMA5 | c.1479T>G p.N493K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV53373817; called by muse, mutect2
- LAMB4 | c.1793T>C p.F598S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV52732451; called by muse, mutect2, varscan2
- LAP3 | c.668T>A p.L223H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV56902040; called by muse, mutect2, varscan2
- LARP6 | c.926A>G p.E309G | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs368859399; called by muse, mutect2, varscan2
- LAX1 | c.361T>A p.S121T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV65850245, COSV65850315; called by muse, mutect2, varscan2
- LAYN | c.1095A>C p.Q365H (on ENST00000375615 / NM_001258390.1; = p.Q357H on NM_178834.5) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65105683; called by muse, mutect2, varscan2
- LCA5L | c.1422A>C p.E474D | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.116); catalogued as COSV55747615; called by muse, mutect2
- LCT | c.4468A>T p.T1490S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51558516; called by muse, mutect2, varscan2
- LGI2 | c.275T>G p.L92R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV66124238; called by muse, mutect2, varscan2
- LGR6 | c.1828T>A p.L610M (on ENST00000367278 / NM_001017403.1; = p.L558M on NM_021636.3) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55167356; called by muse, mutect2, varscan2
- LHX9 | c.650A>C p.N217T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV61331847; called by muse, mutect2, varscan2
- LIFR | c.2584C>T p.R862* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as rs1436005137, COSV54701309; called by muse, mutect2, varscan2
- LIG3 | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52011715; called by muse, mutect2, varscan2
- LILRA5 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56645528; called by muse, mutect2, varscan2
- LIN7A | c.179A>C p.E60A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV54029056, COSV99691730; called by muse, mutect2, varscan2
- LIN9 | c.995T>G p.L332R (on ENST00000366808 / NM_001270410.2; = p.L277R on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100067912, COSV60247248; called by muse, mutect2, varscan2
- LIPF | c.404T>A p.V135D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV53286660; called by mutect2, varscan2
- LIPJ | c.526T>G p.L176V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV64246249; called by muse, mutect2, varscan2
- LMNB2 | c.1474T>C p.S492P | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57591070; called by muse, mutect2, varscan2
- LOX | c.450A>C p.E150D | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV50242200; called by muse, mutect2
- LPA | c.5932C>T p.H1978Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.96); catalogued as rs1484279584, COSV60300747, COSV60313831; called by muse, mutect2, varscan2
- LPO | c.2136T>G p.N712K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51863073; called by muse, mutect2
- LRFN1 | c.899T>G p.L300R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50510621; called by muse, mutect2, varscan2
- LRRC30 | c.296T>G p.L99R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67302403; called by muse, mutect2, varscan2
- LRRC66 | c.1219A>C p.K407Q | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58637134; called by muse, mutect2, varscan2
- LRRTM3 | c.388A>T p.R130* | Nonsense Mutation (SNP) | VAF 7/183 reads (4%) | catalogued as COSV63672573; called by muse, mutect2
- LTA | c.226T>C p.S76P | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.245); catalogued as COSV69305412; called by muse, mutect2, varscan2
- LYN | c.870A>C p.E290D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV70206515; called by muse, mutect2, varscan2
- LYST | c.9397A>T p.N3133Y | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV67714997; called by muse, mutect2, varscan2
- LZTS2 | c.166T>G p.F56V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.224); catalogued as COSV64653063; called by muse, mutect2, varscan2
- MAFB | c.896A>G p.E299G | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64827182; called by muse, mutect2, varscan2
- MAGEB2 | c.750A>T p.K250N | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as rs200726761, COSV66782096; called by muse, mutect2, varscan2
- MAGEE1 | c.13A>C p.S5R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV63912348; called by muse, mutect2, varscan2
- MAMLD1 | c.2152A>G p.S718G | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV53373226; called by muse, mutect2
- MAPK10 | c.506A>C p.D169A (on ENST00000359221 / NM_001351625.2; = p.D207A on NM_002753.5) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV60395282; called by mutect2, varscan2
- MAPT | c.1601T>G p.L534R (on ENST00000262410 / NM_001377265.1; = p.L459R on NM_016835.4) | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as COSV52248464; called by muse, mutect2
- MBNL1 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV56836368; called by muse, mutect2
- MCEMP1 | c.134T>G p.F45C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV58041051; called by muse, mutect2, varscan2
- MCOLN3 | c.1450T>G p.S484A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV100352811, COSV62016517; called by muse, mutect2, varscan2
- MDGA1 | c.2612A>T p.K871M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV51802405; called by muse, mutect2, varscan2
- MDGA2 | c.1846T>G p.L616V (on ENST00000399232 / NM_001113498.2; = p.L318V on NM_182830.4) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV62117593; called by muse, mutect2, varscan2
- MDH1B | c.354A>T p.K118N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.135); catalogued as COSV65591927; called by muse, mutect2, varscan2
- MDN1 | c.14807A>T p.Q4936L | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV65531441; called by muse, mutect2, varscan2
- MED15 | c.875A>G p.Q292R | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as COSV53034065; called by muse, mutect2, varscan2
- MFAP4 | c.407A>T p.E136V | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV55192075; called by muse, mutect2
- MGA | c.7429C>T p.Q2477* (on ENST00000219905 / NM_001164273.1; = p.Q2268* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV54955220; called by muse, mutect2
- MICAL1 | c.1490A>G p.K497R | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs751203974, COSV62196614; called by muse, mutect2
- MID2 | c.1443T>A p.Y481* | Nonsense Mutation (SNP) | VAF 32/47 reads (68%) | catalogued as COSV53314782; called by muse, mutect2, varscan2
- MMP12 | c.455T>A p.I152N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV58261832; called by muse, mutect2
- MMP24 | c.1422A>C p.E474D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55773578; called by muse, mutect2, varscan2
- MMP27 | c.435A>C p.K145N | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV52783019; called by muse, mutect2, varscan2
- MOCS1 | c.1910A>C p.*637Sext*20 | Nonstop Mutation (SNP) | VAF 13/221 reads (6%) | catalogued as COSV51421208; called by muse, mutect2
- MOGAT3 | c.653T>G p.L218R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56177338; called by muse, mutect2
- MPND | c.446A>C p.K149T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV53659922; called by muse, mutect2, varscan2
- MRPL32 | c.432A>T p.Q144H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV56239990; called by muse, mutect2, varscan2
- MS4A7 | c.282T>C p.C94= | Splice Region (SNP) | VAF 19/151 reads (13%) | catalogued as COSV55732134; called by muse, mutect2, varscan2
- MSR1 | c.599A>C p.K200T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV50540706; called by muse, mutect2, varscan2
- MST1R | c.599C>G p.A200G | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.398); catalogued as COSV56574661; called by muse, mutect2, varscan2
- MTARC1 | c.547T>G p.F183V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV65056399; called by muse, mutect2, varscan2
- MTCL1 | c.4795T>A p.L1599M (on ENST00000306329 / NM_001378206.1; = p.L1280M on NM_015210.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV60412599; called by muse, mutect2, varscan2
- MTIF2 | c.936A>C p.E312D | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.488); catalogued as COSV55054457; called by muse, mutect2, varscan2
- MTOR | c.1828T>G p.F610V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV100816612, COSV63879033; called by muse, mutect2, varscan2
- MTOR | c.1412A>C p.K471T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV63879038; called by muse, mutect2, varscan2
- MUC16 | c.23824T>G p.S7942A | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV67448832; called by muse, mutect2, varscan2
- MUC17 | c.6185A>C p.N2062T | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60305823; called by muse, mutect2
- MUC7 | c.250T>G p.F84V | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV59220368; called by muse, mutect2, varscan2
- MVK | c.713A>C p.K238T | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV57333160; called by muse, mutect2
- MYBPC2 | c.1398A>C p.K466N | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV63100381; called by muse, mutect2, varscan2
- MYCBP2 | c.12713A>C p.N4238T (on ENST00000357337; = p.N4276T on NM_015057.5) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV62041578; called by muse, mutect2, varscan2
- MYH1 | c.1199A>C p.K400T | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56858178; called by muse, mutect2, varscan2
- MYH2 | c.4865A>C p.K1622T | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55449987; called by muse, mutect2, varscan2
- MYH2 | c.4670T>G p.L1557R | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV55449999; called by muse, mutect2
- MYH6 | c.5454A>C p.E1818D | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59307961; called by muse, mutect2, varscan2
- MYO15A | c.5555A>G p.K1852R | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV52767469; called by muse, mutect2, varscan2
- MYO15A | c.7657T>G p.S2553A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV52767480; called by muse, mutect2
- MYO16 | c.2906A>C p.K969T | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV51785164; called by muse, varscan2
- MYO16 | c.2924A>C p.K975T | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV51821143; called by muse, varscan2
- MYO1E | c.1448A>G p.Q483R | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV55696244; called by muse, mutect2
- MYO1E | c.219T>G p.I73M | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.402); catalogued as COSV55696254; called by muse, mutect2, varscan2
- MYO5A | c.64T>C p.W22R | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62560340, COSV62565289; called by muse, mutect2, varscan2
- MYO7A | c.5693A>T p.K1898M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV68687447; called by muse, mutect2, varscan2
- NAV1 | c.2200A>T p.T734S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV55227448; called by muse, mutect2, varscan2
- NAV2 | c.1778A>T p.K593I (on ENST00000396087 / NM_001244963.2; = p.K570I on NM_145117.5) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62337024; called by muse, mutect2, varscan2
- NBAS | c.1970A>T p.K657M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV55739493; called by muse, mutect2, varscan2
- NCAPD3 | c.4199A>G p.E1400G | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV73188004; called by muse, mutect2
- NCKIPSD | c.1200T>G p.S400R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV53664012; called by muse, mutect2, varscan2
- NCOR1 | c.5393T>A p.L1798Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV51998994; called by muse, mutect2, varscan2
- NCR1 | c.676T>G p.F226V | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.043); catalogued as COSV52558902; called by muse, mutect2
- NDC80 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55249971; called by muse, mutect2, varscan2
- NDUFAB1 | c.429A>C p.E143D | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.035); catalogued as COSV50287756; called by muse, mutect2
- NDUFB6 | c.278A>C p.K93T | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.864); catalogued as COSV63083861; called by muse, mutect2
- NEB | c.12975T>G p.N4325K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.209); catalogued as COSV51464503; called by muse, mutect2, varscan2
- NEB | c.5525A>C p.K1842T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV51464520; called by muse, mutect2, varscan2
- NEK10 | c.2077A>C p.I693L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV58290182; called by muse, mutect2
- NEK4 | c.1576T>C p.S526P | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1403541232, COSV51783804; called by muse, mutect2, varscan2
- NEU3 | c.1366A>G p.S456G | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV53639210; called by muse, mutect2
- NEURL2 | c.456T>G p.F152L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV51945547; called by muse, mutect2, varscan2
- NFATC3 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60480560; called by muse, mutect2, varscan2
- NFIA | c.587A>G p.Q196R | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.838); catalogued as COSV100964192; called by muse, mutect2, varscan2
- NFIL3 | c.591A>C p.E197D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.819); catalogued as COSV52684895; called by muse, mutect2, varscan2
- NFKBID | c.398T>G p.V133G (on ENST00000396901; = p.V285G on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV61730058; called by muse, mutect2, varscan2
- NIM1K | c.79A>C p.S27R | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV58146589; called by muse, mutect2, varscan2
- NINL | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54009701; called by muse, varscan2
- NINL | c.1042T>A p.F348I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV54009708; called by muse, varscan2
- NIPBL | c.4542A>C p.E1514D | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56967714; called by muse, mutect2, varscan2
- NKX6-2 | c.749A>C p.K250T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1343527747, COSV63974135; called by muse, mutect2, varscan2
- NLRP14 | c.339A>C p.Q113H | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV55072832; called by muse, mutect2, varscan2
- NLRP3 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.347); catalogued as rs1131691891, COSV60223742; ClinVar: uncertain significance; called by muse, mutect2
- NLRP3 | c.1363A>G p.S455G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60231799; called by muse, mutect2, varscan2
- NLRP7 | c.646A>G p.S216G | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as COSV60182725; called by muse, mutect2, varscan2
- NLRP9 | c.273G>C p.E91D | Missense Mutation (SNP) | VAF 86/734 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV60468339; called by muse, varscan2
- NOS1 | c.2462A>G p.E821G | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV57622999; called by muse, mutect2
- NPAS3 | c.781C>T p.R261C (on ENST00000356141 / NM_001164749.2; = p.R229C on NM_022123.3) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV60840049; called by muse, mutect2
- NPAS3 | c.1691A>G p.E564G (on ENST00000356141 / NM_001164749.2; = p.E532G on NM_022123.3) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as COSV60865562; called by muse, mutect2, varscan2
- NPY2R | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs759955067, COSV61529734; called by muse, mutect2, varscan2
- NRIP1 | c.2723A>G p.E908G | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV59660705; called by muse, mutect2, varscan2
- NRK | c.3352T>C p.S1118P | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54608185, COSV99689056; called by muse, mutect2, varscan2
- NTN1 | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51489584; called by muse, mutect2, varscan2
- NUBP2 | c.262T>C p.S88P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV51908812; called by muse, mutect2, varscan2
- NUGGC | c.1892A>C p.N631T | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV58439694; called by muse, mutect2, varscan2
- NUP210 | c.702A>C p.E234D | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.664); catalogued as COSV54414937; called by muse, mutect2, varscan2
- NUP214 | c.1215T>G p.N405K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63913500; called by muse, mutect2, varscan2
- NUP214 | c.2564A>G p.E855G | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63913506; called by muse, mutect2, varscan2
- NUP98 | c.4400T>G p.L1467R (on ENST00000359171 / NM_001365126.1; = p.L1450R on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV61439467; called by muse, mutect2, varscan2
- NXPE1 | c.1436A>C p.N479T (on ENST00000424269; = p.N337T on NM_152315.5) | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52633894; called by muse, mutect2, varscan2
- NYAP1 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV55717504, COSV55722473; called by muse, mutect2, varscan2
- OARD1 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55108610; called by muse, mutect2, varscan2
- OGFRL1 | c.96A>C p.E32D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100965813; called by muse, mutect2
- OLFML1 | c.195A>T p.K65N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.299); catalogued as COSV61404250; called by muse, mutect2, varscan2
- OLFML2B | c.854T>G p.L285R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV54200861; called by mutect2, varscan2
- OR10A4 | c.313T>A p.F105I | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.356); catalogued as COSV65842680; called by muse, mutect2, varscan2
- OR10A7 | c.673A>C p.I225L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV58279662; called by muse, mutect2, varscan2
- OR10AD1 | c.476T>G p.F159C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59613201; called by muse, mutect2
- OR10AD1 | c.10A>G p.N4D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV59613208; called by muse, mutect2
- OR10H2 | c.490T>G p.F164V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59947178; called by muse, mutect2, varscan2
- OR11L1 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV63315921; called by muse, mutect2, varscan2
- OR13C3 | c.499A>G p.S167G | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV66166386; called by muse, mutect2
- OR2G6 | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58576021; called by muse, mutect2, varscan2
- OR2M4 | c.625T>C p.F209L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as COSV100141352, COSV60709775, COSV60709879; called by muse, mutect2, varscan2
- OR4K5 | c.458T>C p.L153S | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV60005472; called by muse, mutect2, varscan2
- OR51A4 | c.887A>G p.K296R | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.32); catalogued as COSV66750155; called by muse, mutect2, varscan2
- OR51I2 | c.308T>G p.L103R | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV58299254; called by muse, mutect2, varscan2
- OR51L1 | c.322A>G p.T108A | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); catalogued as COSV58625976; called by muse, mutect2, varscan2
- OR51L1 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58625985; called by muse, mutect2, varscan2
- OR51Q1 | c.677A>C p.N226T | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.257); catalogued as COSV56180764; called by muse, mutect2, varscan2
- OR51V1 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1351833334, COSV58314152, COSV58316548; called by muse, mutect2, varscan2
- OR52E6 | c.899T>G p.I300S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV61433695; called by muse, mutect2, varscan2
- OR56A4 | c.152T>A p.L51H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV58111967; called by muse, mutect2, varscan2
- OR5H6 | c.229T>G p.L77V (on ENST00000642105; = p.L61V on NM_001005479.2) | Missense Mutation (SNP) | VAF 88/330 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV67352182; called by muse, mutect2, varscan2
- OR5M11 | c.794A>C p.K265T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV73141619, COSV73142032; called by muse, mutect2, varscan2
- OR6C68 | c.264A>C p.K88N | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as COSV65564053; called by muse, mutect2, varscan2
- OR6T1 | c.199T>C p.S67P | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58306169, COSV58309815; called by muse, mutect2, varscan2
- OR7D2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60141584; called by muse, mutect2
- OR9K2 | c.845T>G p.F282C (on ENST00000305377; = p.F260C on NM_001005243.1) | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59533617; called by muse, mutect2, varscan2
- ORAI3 | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52693166; called by muse, mutect2, varscan2
- OSBPL10 | c.1596A>C p.Q532H | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67344709; called by muse, mutect2, varscan2
- OSBPL6 | c.2461A>C p.N821H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV51931905; called by muse, mutect2, varscan2
- OTOF | c.3161A>C p.K1054T (on ENST00000272371 / NM_194248.3; = p.K307T on NM_004802.4) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV55522310; called by muse, mutect2, varscan2
- P4HA3 | c.1097T>C p.L366P | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV59044310; called by muse, mutect2, varscan2
- PABPC4 | c.716A>G p.E239G | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs1426168802, COSV63293736; called by muse, mutect2, varscan2
- PADI4 | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV64925312; called by muse, mutect2, varscan2
- PARD6B | c.625T>G p.L209V | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65405353; called by muse, mutect2
- PARM1 | c.376A>C p.S126R | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV56660556; called by muse, mutect2, varscan2
- PARP14 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV71735666; called by muse, mutect2, varscan2
- PARP14 | c.1376A>C p.K459T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV71735667; called by muse, mutect2, varscan2
- PBRM1 | c.3151T>G p.F1051V (on ENST00000296302 / NM_001366071.2; = p.F1026V on NM_018313.5) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56308068; called by muse, mutect2, varscan2
- PCARE | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs374283240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH8 | c.1396A>G p.T466A | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV58815273; called by muse, mutect2
- PCDH9 | c.901A>G p.R301G | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV60533998; called by muse, mutect2, varscan2
- PCDHA12 | c.1457A>C p.K486T | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.658); catalogued as COSV100247252, COSV56550896; called by muse, mutect2, varscan2
- PCDHA2 | c.1249A>G p.S417G | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.71); catalogued as COSV65371602; called by muse, mutect2, varscan2
- PCDHA4 | c.1516A>T p.S506C | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63546698; called by muse, varscan2
- PCDHA7 | c.50T>G p.F17C | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.289); catalogued as COSV65348056; called by muse, mutect2, varscan2
- PCDHA9 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100970169; called by muse, mutect2
- PCDHB1 | c.727T>A p.S243T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as rs782654150, COSV60633609; called by muse, mutect2, varscan2
- PCDHB1 | c.900A>C p.E300D | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs1554267223, COSV60633616; called by muse, mutect2, varscan2
- PCDHB9 | c.410A>C p.E137A | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV53384484; called by muse, mutect2, varscan2
- PCDHGA10 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV54044946; called by muse, mutect2, varscan2
- PCDHGA3 | c.2104T>A p.C702S | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.285); catalogued as COSV54044856; called by muse, mutect2
- PCDHGB4 | c.869T>G p.F290C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54044894; called by muse, mutect2, varscan2
- PCDHGB5 | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54044916; called by muse, mutect2, varscan2
- PCDHGB6 | c.628T>G p.L210V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54044930; called by muse, mutect2, varscan2
- PCDHGB6 | c.2108T>A p.F703Y | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54044938; called by muse, mutect2
- PCLO | c.5477C>T p.P1826L | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs1562882411; called by muse, mutect2
- PCLO | c.482A>C p.N161T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV61671771; called by muse, mutect2, varscan2
- PCM1 | c.4732A>G p.S1578G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.403); catalogued as COSV59589096; called by muse, mutect2
- PCNT | c.3875A>C p.E1292A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV64033578; called by muse, mutect2, varscan2
- PCNX2 | c.5276A>G p.E1759G | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50920262; called by muse, mutect2, varscan2
- PCSK2 | c.645A>C p.E215D | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52744537; called by muse, mutect2
- PCSK5 | c.1411A>G p.S471G | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV65097530; called by muse, mutect2, varscan2
- PDE1B | c.1378T>G p.F460V | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as COSV54496774; called by muse, mutect2, varscan2
- PDE8A | c.1165A>T p.I389F | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs769772414, COSV59641024; called by muse, mutect2, varscan2
- PDE9A | c.269T>G p.V90G | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52332272; called by muse, mutect2, varscan2
- PEX6 | c.1963T>G p.L655V | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV55101838, COSV55105900; called by muse, mutect2, varscan2
- PGAP1 | c.1940A>C p.K647T | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.755); catalogued as COSV61330375; called by muse, mutect2, varscan2
- PGBD5 | c.623A>G p.K208R (on ENST00000525115; = p.K277R on NM_001258311.2) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs911331397, COSV100358282, COSV58414042; called by muse, mutect2, varscan2
- PHF3 | c.5262T>A p.F1754L | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV50346150; called by muse, mutect2, varscan2
- PHKA2 | c.2800T>C p.C934R | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1296491621, COSV66056697; called by muse, mutect2, varscan2
- PHOX2B | c.545A>C p.D182A | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV56931843; called by muse, mutect2, varscan2
- PIBF1 | c.591A>C p.E197D | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV58328846; called by muse, mutect2, varscan2
- PIBF1 | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as COSV58328855; called by muse, mutect2, varscan2
- PIGB | c.278T>G p.V93G | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51244315; called by muse, mutect2, varscan2
- PIK3CA | c.2230T>A p.F744I | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV55982794, COSV56008181; called by muse, mutect2, varscan2
- PIP5K1C | c.752A>G p.K251R | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV58956473; called by muse, mutect2
- PIWIL4 | c.226A>C p.N76H | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV54412906; called by muse, mutect2
- PKHD1 | c.10241T>G p.I3414S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs145268428; called by muse, mutect2, varscan2
- PLA2G4C | c.15A>C p.E5D | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV62788295; called by muse, mutect2, varscan2
- PLA2G4E | c.1604C>A p.P535H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475968651, COSV68152664; called by muse, mutect2, varscan2
- PLAT | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); catalogued as COSV54278522; called by muse, mutect2
- PLBD1 | c.165A>C p.Q55H | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.587); catalogued as COSV53696743; called by muse, mutect2, varscan2
- PLCD4 | c.212A>C p.N71T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.167); catalogued as COSV68843535; called by muse, mutect2, varscan2
- PLCG2 | c.2129T>C p.F710S | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63877308; called by muse, mutect2, varscan2
- PLEKHA5 | c.2454A>C p.E818D | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV54713523; called by muse, mutect2, varscan2
- PLEKHG1 | c.2458T>G p.L820V | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.058); catalogued as COSV62051591; called by muse, mutect2, varscan2
- PLEKHH2 | c.4274T>G p.L1425R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV56761926; called by muse, mutect2, varscan2
- PLEKHO1 | c.194A>C p.N65T | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV50311620; called by muse, mutect2
- PLIN1 | c.1120T>C p.S374P | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV100261759; called by muse, mutect2, varscan2
- PLIN2 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs767614779, COSV52804555; called by muse, mutect2, varscan2
- PLOD2 | c.1696T>G p.F566V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV51469774; called by muse, mutect2, varscan2
- PLPPR4 | c.1084A>G p.N362D | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.07); catalogued as COSV64567869; called by muse, mutect2, varscan2
- PLTP | c.1418A>G p.E473G | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV51945550; called by muse, varscan2
- PLXNC1 | c.4103T>G p.L1368R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51584993; called by muse, mutect2, varscan2
- PMS1 | c.1378A>C p.S460R | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as COSV59720623; called by muse, mutect2
- PNLIP | c.1170-2A>G p.X390_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as COSV65042126; called by muse, varscan2
- PNPLA7 | c.116T>G p.F39C | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.634); catalogued as COSV53007783; called by muse, mutect2, varscan2
- POGZ | c.1889A>C p.N630T | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV55042894; called by muse, mutect2, varscan2
- POLD2 | c.722T>G p.V241G | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56261679; called by muse, mutect2, varscan2
- POLK | c.604T>G p.L202V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54040379; called by muse, mutect2, varscan2
- POLQ | c.1424A>T p.K475M | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV51762639; called by muse, mutect2, varscan2
- POTEH | c.179A>C p.K60T | Missense Mutation (SNP) | VAF 86/564 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.285); catalogued as COSV58887510; called by muse, varscan2
- PPFIA1 | c.3262T>G p.F1088V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99558106; called by muse, mutect2, varscan2
- PPL | c.492A>C p.Q164H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62051490; called by muse, mutect2, varscan2
- PPM1H | c.1057T>C p.F353L | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.191); catalogued as COSV57379800; called by muse, mutect2, varscan2
- PPP1R16B | c.104A>C p.K35T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55385753; called by muse, mutect2
- PPP1R17 | c.91T>G p.S31A | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.355); catalogued as COSV59612747; called by muse, mutect2, varscan2
- PPP3CC | c.791T>G p.F264C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51503729; called by muse, mutect2, varscan2
- PRDM13 | c.1898A>C p.E633A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV65030785; called by muse, mutect2, varscan2
- PREPL | c.452T>G p.L151R | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV53219634; called by muse, mutect2
- PRKAA2 | c.1501A>T p.S501C | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as COSV64806979; called by muse, mutect2, varscan2
- PRKACA | c.639C>G p.S213R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs1187481745, COSV58069086, COSV58070497; called by muse, mutect2, varscan2
- PRKCQ | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.985); catalogued as COSV54120203; called by muse, mutect2, varscan2
- PRKDC | c.7031T>C p.L2344P | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV58065725; called by muse, mutect2, varscan2
- PRKG2 | c.890A>C p.K297T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52332906; called by muse, mutect2
- PRND | c.514T>C p.W172R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59897488; called by muse, mutect2, varscan2
- PRR11 | c.871A>T p.S291C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV51879625; called by muse, mutect2, varscan2
- PRR14 | c.1722A>C p.E574D | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV54913958; called by muse, mutect2, varscan2
- PSD | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs374100138; called by muse, varscan2
- PSG6 | c.906T>G p.N302K | Missense Mutation (SNP) | VAF 11/307 reads (4%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.699); catalogued as COSV99414672; called by muse, mutect2
- PTCH1 | c.2231T>C p.L744P | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV59496454; called by muse, mutect2
- PTCH1 | c.682A>C p.I228L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV59496484; called by muse, mutect2, varscan2
- PTCHD1 | c.766T>G p.S256A | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV65059034; called by muse, mutect2, varscan2
- PTGFRN | c.1772A>G p.K591R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.18); catalogued as COSV67799748; called by muse, mutect2, varscan2
- PTGS2 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); catalogued as COSV66569313, COSV66569968; called by muse, mutect2, varscan2
- PTPN2 | c.546T>G p.D182E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58999567; called by muse, mutect2, varscan2
- PTPRD | c.161A>C p.K54T | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV61985811; called by muse, mutect2, varscan2
- PWWP3B | c.596T>A p.L199H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.729); catalogued as COSV61801944; called by muse, mutect2, varscan2
- PXK | c.599T>G p.L200R | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV57095023; called by muse, mutect2, varscan2
- PZP | c.2187T>G p.S729R | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54371498; called by muse, mutect2, varscan2
- RAB6B | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs1311764888, COSV53316030; called by muse, mutect2, varscan2
- RACGAP1 | c.1241A>G p.D414G | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56701351; called by muse, mutect2
- RAD17 | c.1081A>T p.K361* (on ENST00000380774 / NM_133339.2; = p.K350* on NM_002873.1) | Nonsense Mutation (SNP) | VAF 40/115 reads (35%) | catalogued as COSV51459799; called by muse, mutect2, varscan2
- RAD54L2 | c.1522T>C p.F508L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56581929; called by muse, mutect2, varscan2
- RAD54L2 | c.4358A>C p.D1453A | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV56581937; called by muse, mutect2, varscan2
- RAE1 | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV64799091; called by muse, mutect2, varscan2
- RAET1E | c.747A>C p.Q249H | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.127); catalogued as COSV61723256; called by muse, mutect2, varscan2
- RALBP1 | c.1730T>G p.I577S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV50039974; called by muse, mutect2, varscan2
- RANBP17 | c.2708T>G p.I903S | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV66658075; called by muse, mutect2, varscan2
- RARS1 | c.533T>G p.L178R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs748949977, COSV51566333; called by muse, mutect2, varscan2
- RARS2 | c.1015T>G p.F339V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV65763088; called by muse, mutect2, varscan2
- RASGRF1 | c.509A>C p.E170A | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV69183772; called by muse, mutect2
- RBBP8 | c.1670A>T p.E557V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV59096322; called by muse, mutect2, varscan2
- RBM27 | c.1198A>C p.S400R | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV54595266; called by muse, mutect2
- RBM27 | c.2483A>C p.K828T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV54595274; called by muse, mutect2, varscan2
- RBM47 | c.973T>C p.S325P | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as COSV55944176; called by muse, mutect2, varscan2
- RBSN | c.1586A>C p.E529A | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.423); catalogued as COSV53795884; called by muse, mutect2, varscan2
- RELN | c.6490A>G p.K2164E | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.679); catalogued as COSV59036722; called by muse, mutect2, varscan2
- RFPL1 | c.848T>C p.F283S | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62978730; called by muse, mutect2
- RGL3 | c.1127T>C p.L376P | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1232433211, COSV63387286; called by muse, mutect2, varscan2
- RGS16 | c.122A>G p.K41R | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV62376030; called by muse, mutect2, varscan2
- RHOBTB1 | c.944A>T p.K315M | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV61959567; called by muse, mutect2, varscan2
- RIC1 | c.1253A>C p.N418T | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV52616133; called by muse, mutect2
- RIOK1 | c.1595A>C p.K532T | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53573686; called by muse, mutect2
- RLN1 | c.506A>C p.E169A | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV56347226; called by muse, varscan2
- RNASE10 | c.592A>C p.K198Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV60518398; called by muse, mutect2, varscan2
- RNF122 | c.185A>C p.K62T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV56360221; called by muse, mutect2
- RNF31 | c.2729A>T p.K910I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as COSV60729064; called by muse, mutect2, varscan2
- ROBO1 | c.4694A>G p.N1565S | Missense Mutation (SNP) | VAF 148/576 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1383050067, COSV71398970; called by muse, mutect2, varscan2
- RP1 | c.5748A>C p.Q1916H | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55128252; called by muse, mutect2, varscan2
- RPE65 | c.182T>G p.F61C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52018945; called by muse, mutect2, varscan2
- RPGR | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.049); catalogued as COSV58838182, COSV58840521; called by muse, mutect2, varscan2
- RPL39L | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV56220448; called by muse, mutect2
- RPL3L | c.958T>G p.F320V | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51908670; called by muse, mutect2, varscan2
- RPSA | c.329A>T p.N110I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV57192112; called by muse, mutect2, varscan2
- RPUSD2 | c.1367A>G p.E456G | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV59766489; called by muse, mutect2, varscan2
- RRBP1 | c.2961T>C p.T987= (on ENST00000377813 / NM_001365613.2; = p.T554= on NM_004587.3) | Splice Region (SNP) | VAF 5/41 reads (12%) | catalogued as rs773439510, COSV55709480; called by mutect2, varscan2
- RRM2 | c.1034A>C p.N345T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV58818052; called by muse, mutect2, varscan2
- RSU1 | c.797A>C p.K266T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61716735; called by muse, mutect2, varscan2
- RTF2 | c.916T>G p.F306V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV50131884; called by muse, mutect2
- RTN3 | c.1791A>C p.E597D (on ENST00000377819 / NM_001265589.2; = p.E578D on NM_201428.3) | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV58032850; called by muse, mutect2, varscan2
- RUFY2 | c.1268A>C p.K423T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV56261167; called by muse, mutect2, varscan2
- RYR1 | c.8177A>C p.K2726T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV62105081, COSV62112502; called by muse, mutect2, varscan2
- RYR2 | c.4112A>T p.N1371I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100772854, COSV63718178; called by muse, mutect2, varscan2
- RYR2 | c.5191G>A p.E1731K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV100771017, COSV63679023; called by muse, mutect2, varscan2
- RYR2 | c.7330A>T p.T2444S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV63718196; called by muse, mutect2, varscan2
- SACS | c.10706T>G p.L3569R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV66547494; called by muse, mutect2, varscan2
- SACS | c.8919T>G p.D2973E | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.637); catalogued as COSV66547504; called by muse, mutect2, varscan2
- SACS | c.7263T>G p.F2421L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.031); catalogued as COSV66547510; called by muse, mutect2, varscan2
- SALL4 | c.1142A>C p.K381T | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV53856646; called by muse, mutect2, varscan2
- SAP130 | c.2504A>C p.K835T | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.536); catalogued as COSV52103627; called by muse, mutect2, varscan2
- SCD5 | c.859T>G p.F287V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV60299555; called by muse, mutect2, varscan2
- SCML1 | c.928A>G p.T310A (on ENST00000380041 / NM_001037540.3; = p.T283A on NM_006746.6) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV66241062; called by muse, mutect2
- SCN10A | c.197T>C p.F66S | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs761786138, COSV71862774; called by muse, mutect2
- SCN11A | c.2965A>T p.S989C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56579401; called by muse, mutect2, varscan2
- SCN11A | c.2756T>G p.L919R | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56579409; called by muse, mutect2, varscan2
- SCN1A | c.1463A>C p.K488T | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.422); catalogued as COSV57678755; called by muse, mutect2, varscan2
- SCN2A | c.3147A>C p.K1049N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.371); catalogued as COSV51857195; called by muse, mutect2
- SCN2A | c.4438A>G p.K1480E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV51857216; called by muse, mutect2, varscan2
- SCP2D1 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.521); catalogued as rs200754774, COSV53858930; called by muse, mutect2, varscan2
- SDK2 | c.2588A>C p.K863T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV66190966, COSV66198192; called by muse, mutect2, varscan2
- SDR42E1 | c.629A>C p.K210T | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as rs1312549079, COSV61095204; called by muse, mutect2, varscan2
- SEC11C | c.565A>C p.K189Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55312475; called by muse, mutect2, varscan2
- SEC23B | c.262T>C p.C88R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52724359; called by muse, mutect2, varscan2
- SEC24D | c.1796A>C p.K599T | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV54885521; called by muse, mutect2
- SEC31B | c.599A>T p.K200M | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64825223; called by muse, mutect2
- SEMA4F | c.1280T>A p.L427Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60285525; called by muse, mutect2, varscan2
- SEMA7A | c.1469T>C p.L490P | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56092669; called by muse, mutect2, varscan2
- SEMG2 | c.1587A>C p.Q529H | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as COSV65648046; called by muse, mutect2, varscan2
- SERAC1 | c.1406A>G p.K469R | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.11); catalogued as COSV65598172; called by muse, mutect2, varscan2
- SERPINB11 | c.131T>G p.L44R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66957917; called by muse, mutect2, varscan2
- SERPINB2 | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV55095265; called by muse, mutect2, varscan2
- SERPINB3 | c.253T>A p.F85I | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV52194678; called by muse, mutect2, varscan2
- SERPINB4 | c.253T>A p.F85I | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100346029; called by muse, mutect2, varscan2
- SESN3 | c.549T>G p.N183K | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); catalogued as COSV53587720; called by muse, mutect2
- SETD2 | c.5015+2T>C p.X1672_splice | Splice Site (SNP) | VAF 51/212 reads (24%) | catalogued as rs1163395247, COSV57453799; called by muse, mutect2, varscan2
- SGIP1 | c.689T>G p.I230S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); catalogued as COSV52780050; called by muse, mutect2, varscan2
- SHOX | c.370T>G p.F124V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM074522, COSV61862507; called by muse, mutect2, varscan2
- SIMC1 | c.1480T>G p.F494V (on ENST00000443967 / NM_001308196.1; = p.F79V on NM_198567.5) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57908015; called by muse, mutect2, varscan2
- SIPA1L1 | c.1982T>G p.L661R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62174205; called by muse, mutect2, varscan2
- SIPA1L1 | c.2906A>C p.N969T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100665236, COSV62174211; called by muse, mutect2, varscan2
- SLC12A2 | c.1774-2A>G p.X592_splice | Splice Site (SNP) | VAF 8/68 reads (12%) | catalogued as COSV52477188; called by muse, varscan2
- SLC13A1 | c.793T>G p.F265V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52017525; called by muse, mutect2, varscan2
- SLC16A14 | c.1073T>G p.I358S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54621683; called by muse, mutect2, varscan2
- SLC17A4 | c.870A>C p.K290N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV64957438; called by muse, mutect2, varscan2
- SLC17A6 | c.1155A>T p.R385S | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54142400; called by muse, mutect2, varscan2
- SLC19A3 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV51455044; called by muse, mutect2, varscan2
- SLC1A1 | c.21A>C p.K7N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52052588, COSV52058566; called by muse, mutect2, varscan2
- SLC1A6 | c.1524C>A p.N508K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55674369, COSV55674690; called by muse, mutect2, varscan2
- SLC22A9 | c.1343T>C p.L448P | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV54170797; called by muse, mutect2, varscan2
- SLC22A9 | c.1624A>C p.K542Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV54170807; called by muse, mutect2, varscan2
- SLC25A51 | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV54253879; called by muse, mutect2
- SLC27A2 | c.1399T>A p.L467I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV51063940; called by muse, mutect2, varscan2
- SLC30A5 | c.2007A>C p.K669N | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.089); catalogued as COSV67450690; called by muse, mutect2
- SLC35F3 | c.661A>C p.M221L (on ENST00000366617 / NM_001300845.1; = p.M290L on NM_173508.4) | Missense Mutation (SNP) | VAF 44/383 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV64021932; called by muse, mutect2, varscan2
- SLC4A4 | c.2684C>T p.P895L (on ENST00000264485 / NM_001098484.3; = p.P851L on NM_003759.4) | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52640167; called by muse, mutect2
- SLC6A20 | c.940A>T p.S314C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV62072999; called by muse, mutect2, varscan2
- SLC7A14 | c.919T>G p.L307V | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV51591231; called by muse, mutect2, varscan2
- SLC8A2 | c.1341-2A>T p.X447_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV52643314; called by muse, mutect2, varscan2
- SLC8A2 | c.1265A>T p.E422V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV52643323; called by muse, mutect2, varscan2
- SLC8A3 | c.2380T>G p.F794V (on ENST00000381269 / NM_183002.3; = p.F792V on NM_033262.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53693084; called by muse, mutect2, varscan2
- SLC9A9 | c.1171A>G p.I391V | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs138653730; called by muse, mutect2, varscan2
- SLFN13 | c.1538A>C p.K513T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV99540475; called by mutect2, varscan2
- SLIT1 | c.1724A>G p.N575S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56600454; called by muse, mutect2, varscan2
- SLIT3 | c.1790A>G p.H597R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60635243; called by muse, mutect2, varscan2
- SMG8 | c.1088A>T p.D363V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV56287365; called by muse, mutect2, varscan2
- SMYD4 | c.431A>T p.K144M | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59713892; called by muse, mutect2, varscan2
- SNED1 | c.2238T>G p.S746R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60034428; called by muse, mutect2, varscan2
- SOAT1 | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV62657252; called by muse, mutect2, varscan2
- SOCS5 | c.255A>T p.E85D | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV60606617; called by muse, mutect2
- SORCS3 | c.2363T>G p.L788R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV63799074; called by muse, mutect2, varscan2
- SOS1 | c.1132A>T p.T378S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.045); catalogued as COSV67673689; called by muse, mutect2, varscan2
- SPAG16 | c.1363T>C p.S455P | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59131275; called by muse, mutect2, varscan2
- SPAG17 | c.3618A>C p.E1206D | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.932); catalogued as COSV60457494; called by muse, mutect2, varscan2
- SPAG17 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as rs746632438, COSV60453592; called by muse, mutect2, varscan2
- SPATA16 | c.413A>C p.E138A | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63533756; called by muse, mutect2, varscan2
- SPATA22 | c.445A>T p.S149C | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV52154904; called by muse, mutect2, varscan2
- SPHKAP | c.5037C>A p.C1679* (on ENST00000392056 / NM_001142644.2; = p.C1650* on NM_030623.3) | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as COSV60896137; called by muse, mutect2, varscan2
- SPHKAP | c.4159T>G p.L1387V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV60896151; called by muse, mutect2
- SPRING1 | c.188T>G p.F63C | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.43); catalogued as COSV54340105; called by muse, mutect2
- SPRR2D | c.199T>G p.C67G | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.266); catalogued as COSV64209590; called by muse, mutect2, varscan2
- SPRY4 | c.298A>G p.S100G (on ENST00000434127 / NM_001127496.3; = p.S123G on NM_030964.4) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.956); catalogued as COSV59986912; called by muse, mutect2, varscan2
- SPTB | c.3835T>G p.F1279V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV67635484; called by muse, mutect2, varscan2
- SPTLC3 | c.1534A>G p.M512V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.052); catalogued as COSV65469040; called by muse, mutect2, varscan2
- SQOR | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs778928942, COSV52943801; called by muse, mutect2, varscan2
- SRCAP | c.3598A>T p.N1200Y | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV52682077; called by muse, mutect2, varscan2
- SSB | c.48A>C p.K16N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99642415; called by muse, mutect2
- ST7L | c.1121A>C p.K374T | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58312565; called by muse, mutect2, varscan2
- STOX2 | c.2633A>C p.N878T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as COSV57857071; called by muse, mutect2, varscan2
- STRAP | c.996A>C p.E332D | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV50309172, COSV50309451; called by muse, mutect2, varscan2
- SUN3 | c.229A>G p.K77E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as COSV52054590; called by muse, mutect2, varscan2
- SVEP1 | c.3492T>G p.S1164R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV57049291; called by muse, mutect2, varscan2
- SYCP1 | c.725A>C p.K242T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65696794; called by muse, mutect2, varscan2
437 further variants in this file (189 protein-altering or splice-affecting, 224 silent, 24 other) are not listed here.
